Gene-level copy-number profile of tumor specimen TCGA-DX-A3U5-01A from TCGA case TCGA-DX-A3U5, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 52.3 years (19,088 days).
Specimen TCGA-DX-A3U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.92b66271-a319-4c66-87e1-f2d354b95eb5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3U5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6d71521c-bade-45c9-9233-dbef34918d89

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 13,002; copy number 2: 40,127; copy number 3: 4,814; copy number 4: 485; copy number 5: 424; copy number 6: 144; copy number 7: 97; copy number 8: 45; copy number 11: 77; copy number 12: 78; copy number 13: 44; copy number 14: 13; copy number 15: 31; copy number 16: 31; copy number 17: 4; copy number 18: 76; copy number 19: 94; copy number 20: 12; copy number 22: 97; copy number 23: 34; copy number 24: 28; copy number 25: 3; copy number 26: 2; copy number 27: 7; copy number 28: 4; copy number 31: 14; copy number 35: 2; copy number 42: 2; copy number 46: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3U5-01A-11D-A227-01): tumor purity 0.62, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,929,457–22,128,103, 8 genes (within-gene range 0–1): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,364 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:97,916,353–98,443,858, 6 genes, copy number 5–7: CRYZP2, RPL5P12, DUTP8, AC019077.1, RAP1GDS1, AC058823.1.
- chr4:99,304,971–99,654,648, 9 genes, copy number 5: ADH1B, ADH1C, ADH7, AP001960.1, C4orf17, TRMT10A, MTTP, AC083902.1, C4orf54.
- chr4:109,303,035–112,231,596, 52 genes, copy number 5: COL25A1-DT, RBMXP4, SEC24B-AS1, SEC24B, RN7SL55P, MIR576, SETP20, CDC42P4, MCUB, HIGD1AP14, CASP6, AC004067.1, PLA2G12A, AC126283.2, CFI, AC126283.1, GAR1, RRH, LRIT3, KRT19P3, EGF, RNU6-35P, ELOVL6, RN7SL275P, AC093770.1, HSBP1P2, RNF14P2, RNU6-205P, ZBED1P1, ENPEP, RPL7L1P13, ZNF969P, AC093872.1, AC098798.1, PANCR, PITX2, LINC01438, MIR297, LYPLA1P2, AC004062.1, RNU6-289P, AC083795.1, AC083795.2, AC139718.2, AC139718.1, AC004704.1, CCDC34P1, TUBB8P3, AC093663.1, FAM241A, AC093663.2, AC109347.1.
- chr5:162,000,057–163,437,326, 4 genes, copy number 5 (within-gene range 2–5): GABRG2, AC113414.1, RNU6-164P, ARL2BPP5.
- chr6:129,576,132–130,443,067, 10 genes, copy number 7 (within-gene range 2–7): ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A.
- chr6:131,628,442–134,707,349, 81 genes, copy number 6–16 (broad region; genes not listed).
- chr6:135,497,422–151,391,559, 261 genes, copy number 6–18 (within-gene range 2–18) (broad region; genes not listed).
- chr7:23,100,214–23,177,914, 3 genes, copy number 13 (within-gene range 2–13): KLHL7-DT, KLHL7, AK3P3.
- chr12:66,767–1,495,933, 29 genes, copy number 5 (within-gene range 2–5): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2.
- chr12:1,917,951–5,406,651, 95 genes, copy number 5 (broad region; genes not listed).
- chr12:54,682,973–54,896,008, 3 genes, copy number 25 (within-gene range 2–25): AC079310.1, VDAC1P5, MUCL1.
- chr12:57,546,026–58,105,935, 39 genes, copy number 22: KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:65,824,460–65,966,291, 4 genes, copy number 12: HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,950,754–68,451,663, 27 genes, copy number 13–24 (within-gene range 2–24): AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1.
- chr12:68,642,519–68,971,570, 15 genes, copy number 20–46: ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,326,574–71,441,898, 36 genes, copy number 8–23 (within-gene range 2–23): AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8.
- chr12:71,839,707–74,664,141, 27 genes, copy number 7–28: TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1.
- chr12:76,858,709–77,317,234, 6 genes, copy number 5–27: CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464.
- chr12:78,052,181–78,540,675, 6 genes, copy number 13–42: AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1.
- chr12:80,935,736–81,998,962, 11 genes, copy number 5–7: MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1.
- chr12:82,673,070–83,172,740, 5 genes, copy number 20–35: AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1.
- chr12:84,671,598–85,264,457, 5 genes, copy number 13–27 (within-gene range 2–27): AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1.
- chr12:88,492,793–94,307,675, 100 genes, copy number 13–19 (within-gene range 3–19) (broad region; genes not listed).
- chr12:94,834,147–98,516,422, 79 genes, copy number 6–24 (within-gene range 6–26) (broad region; genes not listed).
- chr12:100,143,058–100,628,288, 14 genes, copy number 6: AC010203.2, GOLGA2P5, RN7SL176P, AC010203.1, MIR1827, ACTR6, DEPDC4, Y_RNA, SCYL2, SLC17A8, NR1H4, AC010200.1, GAS2L3, PIGAP1.
- chr12:102,395,874–103,506,174, 12 genes, copy number 5–16: IGF1, AC010202.1, LINC00485, PAH, AC026108.1, ASCL1, AC026108.2, AC068643.1, AC068643.2, C12orf42, AC084364.1, AC084364.2.
- chr12:108,738,484–110,746,206, 64 genes, copy number 5–23 (broad region; genes not listed).
- chr12:111,034,165–111,600,256, 11 genes, copy number 16 (within-gene range 1–16): CUX2, MIR6760, RNA5SP373, PHETA1, LINC02356, HSPA8P14, SH2B3, ATXN2, U7, IFITM3P5, ATXN2-AS.
- chr12:111,839,764–112,023,449, 10 genes, copy number 11–15: MAPKAPK5-AS1, MAPKAPK5, RPS2P41, ADAM1A, ADAM1B, TMEM116, SLC25A3P2, AC004024.1, ERP29, AC073575.2.
- chr12:112,037,599–112,065,755, 2 genes, copy number 13: MIR3657, AC073575.1.
- chr12:112,906,783–114,113,489, 34 genes, copy number 15–20 (within-gene range 2–20): OAS1, AC004551.1, OAS3, OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL, LHX5, LHX5-AS1, LINC01234, DYNLL1P4, RBM19, AC009731.1, AC073863.1, AC010183.1, AC010183.2, HAUS8P1, GLULP5.
- chr12:122,920,951–122,982,913, 4 genes, copy number 8: ABCB9, OGFOD2, AC026362.1, ARL6IP4.
- chr12:131,165,011–131,529,894, 15 genes, copy number 12: LINC01257, AC126564.1, RPS6P20, AC092850.1, LINC02415, RNA5SP376, AC092850.2, LINC02370, AC140118.2, AC140118.1, AC073578.4, AC073578.2, AC073578.5, AC073578.1, AC073578.3.
- chr12:131,661,063–131,945,896, 14 genes, copy number 11 (within-gene range 3–11): RNA5SP377, AC117500.1, RPS6P21, SFSWAP, AC117500.2, RNA5SP378, RNU6-1017P, MMP17, AC131009.2, ULK1, AC131009.4, AC131009.1, PUS1, AC131009.3.
- chr16:6,748,908–8,112,756, 9 genes, copy number 7–8 (within-gene range 3–8): RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1.
- chr16:10,326,434–15,932,294, 165 genes, copy number 5–8 (broad region; genes not listed).
- chr17:4,710,596–5,175,034, 41 genes, copy number 7: ARRB2, MED11, AC091153.4, CXCL16, ZMYND15, TM4SF5, VMO1, AC233723.2, GLTPD2, PSMB6, AC233723.1, PLD2, MINK1, ATP6V0CP1, RN7SL784P, CHRNE, C17orf107, GP1BA, SLC25A11, RNF167, PFN1, ENO3, SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1, SLC52A1, AC012146.1, AC012146.2, ZFP3, ZNF232, ZNF232-AS1, USP6, AC012146.3.
- chr17:12,760,140–13,100,939, 8 genes, copy number 8: AC005358.1, ARHGAP44, MIR1269B, AC005274.1, AC005277.2, AC005277.1, ELAC2, AC005303.1.
- chr19:1,505,022–1,981,338, 29 genes, copy number 5 (within-gene range 3–5): ADAMTSL5, PLK5, AC027307.1, MEX3D, RN7SL477P, MBD3, AC005943.2, AC005943.1, UQCR11, TCF3, RNU6-1223P, Metazoa_SRP, AC005256.1, ONECUT3, ATP8B3, REXO1, AC012615.2, MIR1909, AC012615.6, AC012615.3, KLF16, AC012615.4, AC012615.1, AC012615.5, ABHD17A, SCAMP4, ADAT3, CSNK1G2, CSNK1G2-AS1.
- chr19:1,989,401–2,003,581, 2 genes, copy number 5: AC005306.1, AC004678.2.

Autosomal genes at a single copy (total copy number 1): 10,589. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
